Gene-level copy-number profile of tumor specimen TCGA-FP-7916-01A from TCGA case TCGA-FP-7916, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.0 years (28,475 days).
Specimen TCGA-FP-7916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.87bb178f-49b2-4769-b9ba-68053d5988f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-7916-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed28dcdc-9c71-43fc-a724-e0e339e8dbed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 63; copy number 2: 15,491; copy number 3: 28,607; copy number 4: 6,868; copy number 5: 8,780.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-7916-01A-11D-2200-01): tumor purity 0.3, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–2): FHIT.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr6:148,001,716–148,020,974, 2 genes: AL445123.2, AL445123.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 63. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
